Somatic mutation profile of tumor specimen TCGA-CG-5719-01A (aliquot TCGA-CG-5719-01A-11D-1600-08) from TCGA case TCGA-CG-5719, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G1; Age at diagnosis: 54.7 years (19,966 days).
Specimen TCGA-CG-5719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d213376-8646-42b7-adb8-32b1f329ea62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5719-10A (Blood Derived Normal), aliquot TCGA-CG-5719-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7e3e5de-80dd-4674-91d6-70a31748b1de

The open-access MAF lists 63 somatic variants for this specimen: 41 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 20, Nonsense Mutation 3, Intron 1, Splice Site 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH15 | c.2785C>T p.R929* | Nonsense Mutation (SNP) | VAF 41/156 reads (26%) | catalogued as rs1057516342, CM050735, COSV57337854; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEP63 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758895747, COSV59676514; called by muse, mutect2, varscan2
- CHRNB4 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs760548392, COSV55717198; called by muse, mutect2, varscan2
- CYP2A13 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57839044; called by muse, mutect2, varscan2
- DNAH1 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs751396355, COSV70232373; called by muse, mutect2, varscan2
- EPHA6 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 75/456 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748675557, COSV67564911; called by muse, mutect2, varscan2
- ESRRG | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV63170974, COSV63179370; called by muse, mutect2, varscan2
- FSTL5 | c.1270G>C p.D424H | Missense Mutation (SNP) | VAF 40/626 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60212289; called by muse, mutect2
- GAL | c.272T>C p.I91T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs1476775656, COSV55764321; called by muse, mutect2, varscan2
- GBF1 | c.3877C>T p.P1293S (on ENST00000369983 / NM_001377137.1; = p.P1292S on NM_004193.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV64147091; called by muse, mutect2
- GOLGA5 | c.626C>G p.P209R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV50834076; called by muse, mutect2, varscan2
- GRM7 | c.1219A>T p.K407* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as COSV63155839; called by muse, mutect2, varscan2
- HCFC2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57559283; called by muse, mutect2
- IGDCC4 | c.1532C>G p.A511G | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61538262; called by muse, mutect2
- IGSF10 | c.375T>A p.F125L | Missense Mutation (SNP) | VAF 73/426 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV56788695; called by muse, mutect2, varscan2
- ITGB8 | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56011562; called by muse, mutect2, varscan2
- KIAA0319 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs141114963; called by muse, mutect2, varscan2
- LMBRD1 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV65298394, COSV65300398; called by muse, mutect2, varscan2
- LRRC4 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.025); catalogued as rs761482598, COSV50815446, COSV50815960; called by muse, mutect2, varscan2
- MUC16 | c.43438C>T p.R14480W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs755907893, COSV66694686; called by muse, mutect2, varscan2
- MUC5B | c.15436G>A p.V5146I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.254); catalogued as rs373377243; called by muse, mutect2, varscan2
- MYH8 | c.3992C>T p.A1331V | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs751289543, COSV67969119; called by muse, mutect2, varscan2
- NLRP4 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1184804697, COSV100015604, COSV56711001; called by muse, mutect2, varscan2
- NR5A1 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291621949, COSV65295161; called by muse, mutect2
- PALD1 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746010656, COSV54976421; called by muse, mutect2, varscan2
- PMFBP1 | c.2517G>C p.K839N (on ENST00000537465; = p.K834N on NM_031293.3) | Missense Mutation (SNP) | VAF 40/473 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52828368; called by muse, mutect2
- PTPRM | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV59871039; called by muse, mutect2, varscan2
- RASSF6 | c.817G>A p.E273K (on ENST00000342081 / NM_201431.2; = p.E241K on NM_177532.5) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56719797; called by muse, mutect2, varscan2
- RBM47 | c.1330+1G>A p.X444_splice | Splice Site (SNP) | VAF 35/249 reads (14%) | catalogued as COSV55939188; called by muse, mutect2, varscan2
- REC8 | c.1390A>T p.M464L | Missense Mutation (SNP) | VAF 5/123 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1566638268, COSV61017449; called by muse, mutect2
- RYR2 | c.6614G>A p.R2205H | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370276573; called by muse, mutect2, varscan2
- SACS | c.2078C>T p.S693L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV66544040; called by muse, mutect2
- TMC2 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV62656027; called by muse, mutect2
- TREML4 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as COSV58385707; called by muse, mutect2, varscan2
- UACA | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV59857778; called by muse, mutect2, varscan2
- WDR62 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54337294; called by muse, mutect2, varscan2
- ZFYVE26 | c.7036C>T p.R2346W | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1223094101, COSV61326046; called by muse, mutect2
- ZNF358 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as rs1285321147, COSV51177917; called by muse, mutect2, varscan2
- CD37 | c.61_62insGCT p.L20_F21insC | In Frame Ins (INS) | VAF 29/250 reads (12%) | called by mutect2, varscan2
- KCNK9 | c.995dup p.Y332* | Nonsense Mutation (INS) | VAF 30/187 reads (16%) | called by mutect2, pindel, varscan2
- AP5S1 | c.510C>T p.L170= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55694373; called by muse, mutect2, varscan2
- ATG2A | c.3003G>A p.P1001= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs75814919, COSV65967755; called by muse, mutect2, varscan2
- C10orf90 | c.429G>A p.T143= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs377010024; called by muse, mutect2, varscan2
- ERBIN | c.126T>C p.F42= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV52322176; called by muse, mutect2, varscan2
- FMN2 | c.1341G>A p.P447= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV60415888; called by muse, mutect2, varscan2
- GPRC5B | c.525C>T p.I175= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV56026778, COSV56027609; called by muse, mutect2
- GRM3 | c.903C>T p.D301= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV64475973; called by muse, mutect2, varscan2
- KCNT2 | c.2515C>T p.L839= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV54093963; called by muse, mutect2, varscan2
- KDM5A | c.51A>G p.P17= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1228340514, COSV66994585; called by muse, mutect2
- MUC16 | c.1971G>A p.K657= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as COSV67479839, COSV67486786; called by muse, mutect2
- NCSTN | c.1968C>T p.I656= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV54189630; called by muse, mutect2, varscan2
- OS9 | c.9G>C p.A3= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as COSV57783907; called by muse, mutect2
- P2RY1 | c.711C>T p.Y237= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs748490359, COSV59309973; called by muse, mutect2, varscan2
- PCNT | c.2841C>T p.A947= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs764838193, COSV64030757; called by muse, mutect2, varscan2
- RAB3A | c.312C>T p.I104= | Silent (SNP) | VAF 9/198 reads (5%) | catalogued as COSV55853279; called by muse, mutect2
- RPS6KB2 | c.1143C>T p.N381= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV57052538; called by muse, mutect2, varscan2
- SHROOM3 | c.4734A>T p.T1578= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV56034774; called by muse, mutect2, varscan2
- SLC9C2 | c.621C>T p.I207= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs556810167, COSV62947355; called by muse, mutect2, varscan2
- TNMD | c.633C>T p.N211= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs200098806, COSV65977497; called by muse, mutect2, varscan2
- ZIC3 | c.1179C>T p.C393= | Silent (SNP) | VAF 39/306 reads (13%) | catalogued as rs754070677, COSV54975512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MASP1 | c.1303+5384G>A | Intron (SNP) | VAF 48/169 reads (28%) | catalogued as rs764178335, COSV56221079, COSV99961690; called by muse, mutect2, varscan2
- SLC22A17 | n.1091G>A | RNA (SNP) | VAF 37/175 reads (21%) | catalogued as COSV52836482; called by muse, mutect2, varscan2
